Gene-level copy-number profile of tumor specimen TCGA-BR-A4J1-01A from TCGA case TCGA-BR-A4J1, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.7 years (23,266 days).
Specimen TCGA-BR-A4J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.83ac7e03-f675-4452-93a8-1aa958026b9a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4J1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ebce8c1-ccec-4b74-b1f6-77525bb3395e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 3,615; copy number 2: 28,420; copy number 3: 21,370; copy number 4: 1,858; copy number 5: 3,858; copy number 6: 571; copy number 7: 24; copy number 9: 8; copy number 18: 13; copy number 20: 1; copy number 22: 9; copy number 32: 45; copy number 33: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4J1-01A-11D-A253-01): tumor purity 0.8, ploidy 2.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:91,108,023–91,325,306, 2 genes: AC004054.1, AC074124.1.
- chr5:59,703,606–60,033,020, 2 genes: MIR582, AC034234.1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,214,672, 12 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,531 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–12,700,889, 244 genes, copy number 5 (broad region; genes not listed).
- chr8:38,970,360–39,995,248, 19 genes, copy number 5 (within-gene range 3–5): AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 5–18 (within-gene range 3–18) (broad region; genes not listed).
- chr12:66,767–23,251,499, 632 genes, copy number 5 (broad region; genes not listed).
- chr12:24,810,024–26,421,462, 41 genes, copy number 32 (within-gene range 4–32): BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:26,335,864–26,373,733, 2 genes, copy number 32: AC055720.2, RNA5SP354.
- chr12:29,500,840–39,539,851, 132 genes, copy number 5–33 (within-gene range 4–33) (broad region; genes not listed).
- chr12:40,692,439–41,072,415, 1 gene, copy number 32 (within-gene range 4–32): CNTN1.
- chr12:40,978,744–42,590,355, 25 genes, copy number 5–32 (within-gene range 2–32): AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3.
- chr13:27,236,282–27,620,529, 12 genes, copy number 6: LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2.
- chr13:39,053,019–114,337,626, 977 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:87,250–16,053,197, 290 genes, copy number 5 (within-gene range 0–5) (broad region; genes not listed).
- chr20:15,552,157–44,069,616, 622 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,198. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
